Somatic mutation profile of tumor specimen 0DVJOH from CCDI case PBCMIJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.6 years (585 days).
Specimen 0DVJOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed847ab9-3119-4f44-a848-8af6be1004f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b00ff4c-c573-415d-baad-b28e8aa429e4

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLK3 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, varscan2
- EGFR | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 94/766 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, varscan2
- GRIP2 | c.3383C>G p.A1128G (on ENST00000619221; = p.A1031G on NM_001080423.4) | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, varscan2
- ATRN | c.3075G>A p.V1025= | Silent (SNP) | VAF 58/322 reads (18%) | called by muse, varscan2
